Surgical pathology report (de-identified scan), TCGA case TCGA-CJ-4899, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CJ-4899-01A (Primary Tumor).

Surgery Date: [REDACTED]

TCGA - CJ - 4899

Pathology Report

DIAGNOSIS

(A) LEFT KIDNEY AND ADRENAL GLAND:

RENAL CELL CARCINOMA, CONVENTIONAL (CLEAR CELL TYPE), FUHRMAN'S NUCLEAR GRADE 2.

TUMOR PUSHES INTO RENAL SINUS ADIPOSE TISSUE. (SEE COMMENT)

TUMOR MEASURES 4.5 CM IN GREATEST DIMENSION.

Vascular and soft tissue margins of resection free of tumor.

Renomedullary interstitial cell tumor (medullary fibroma) (0.5 cm in greatest dimension).

Adrenal gland, no tumor present.

COMMENT

The tumor focally pushes into the renal sinus adipose tissue with a well circumscribed border. Multiple additional deeper sections are examined and no unequivocal invasion into the renal sinus adipose tissue is identified. No extension into the perinephric adipose tissue is identified.

GROSS DESCRIPTION

(A) LEFT KIDNEY AND ADRENAL GLAND - A nephrectomy specimen consisting of a left kidney (15.0 x 10.0 x 6.0 cm), a segment of renal artery, renal vein, ureter (10.5 cm in length x 0.3 cm in average diameter) and an adrenal gland (5.0 x 2.0 x 0.7 cm).

There is a 4.5 x 3.5 x 3.0 cm well-circumscribed tumor in the mid pole of the kidney. The tumor is bright yellow with areas of hemorrhage and necrosis, predominantly within the center. The tumor focally pushes into the renal sinus adipose tissue as a well circumscribed nodule. The tumor abuts renal vein and renal pelvis and does not extend into the renal vein or pelvis. The tumor does not extend into Gerota's fascia.

In addition there is a tan-white nodule (0.4 x 0.4 x 0.5 cm), 0.8 cm from the main tumor.

The pelvicalyceal system is smooth and has a stone (0.3 x 0.3 x 0.3 cm). No lymph nodes are identified in the hilum of the kidney.

Serial cross section of the adrenal gland shows unremarkable cortex and medulla.

Portions of the tumor have been submitted for possible electron microscopy. Specimen photographs are taken. Tumor and normal are submitted for Tumor Bank.

INK CODE: Blue- Gerota's fascia.

SECTION CODE: A1, artery and vein margins, en face; A2-A3, non-neoplastic kidney; A4, adrenal, representative section; A5, A6, tumor in relation to renal vein; A7-A10, tumor in relation to renal sinus; A11, tumor in relation to renal pelvis; A12, tumor with Gerota's fascia; A13-A15, tumor, representative sections; A16, tumor with small nodule [REDACTED]

CLINICAL HISTORY

Left renal mass.

SNOMED CODES

T-71000, M-83123, M-Y1640

Source: NCI Genomic Data Commons file b80a83c2-0149-448b-9b9f-7210ee770c9e (TCGA-CJ-4899.549913D4-C8D1-42D1-9DA6-A7A10480E210.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).